Somatic mutation profile of tumor specimen TARGET-30-PATEPF-01A (aliquot TARGET-30-PATEPF-01A-01D) from TARGET case TARGET-30-PATEPF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.9 years (1,434 days).
Specimen TARGET-30-PATEPF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cac9726a-439b-4f5b-8e8c-ccc10a75b750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATEPF-10A (Blood Derived Normal), aliquot TARGET-30-PATEPF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e79dd0d-7de4-40e5-a101-7ae261649e4b

The open-access MAF lists 35 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 25, Silent 5, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF5 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV51933157; called by muse, mutect2, varscan2
- AK5 | c.778C>G p.Q260E (on ENST00000354567 / NM_174858.3; = p.Q234E on NM_012093.4) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV60968647, COSV60971966; called by muse, mutect2, varscan2
- AOC2 | c.736A>T p.R246W | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53199014, COSV99513492; called by muse, mutect2, varscan2
- ARHGEF17 | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.048); catalogued as COSV55232132; called by muse, mutect2, varscan2
- C9orf135 | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 30/51 reads (59%) | catalogued as COSV65875321; called by muse, mutect2, varscan2
- CD19 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61188454; called by muse, mutect2, varscan2
- CDKN2D | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV57264402; called by muse, mutect2, varscan2
- CDYL | c.1714G>T p.E572* (on ENST00000328908 / NM_001368125.1; = p.E518* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV59359522; called by muse, mutect2, varscan2
- COL15A1 | c.2031G>A p.M677I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1278026409, COSV66644094; called by muse, mutect2, varscan2
- DOCK8 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 101/204 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV66633917; called by muse, mutect2, varscan2
- DUSP22 | c.283A>T p.S95C | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60526518; called by muse, mutect2, varscan2
- FLG | c.6593A>G p.Q2198R | Missense Mutation (SNP) | VAF 170/524 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64241112, COSV99056730; called by muse, varscan2
- FRAS1 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV53607091; called by muse, mutect2, varscan2
- IGSF22 | c.1628del p.E543Gfs*5 | Frame Shift Del (DEL) | VAF 45/114 reads (39%) | catalogued as COSV60033686; called by mutect2, pindel, varscan2
- KCTD18 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63344283; called by muse, mutect2, varscan2
- MET | c.3548G>A p.G1183D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59260677; called by muse, mutect2, varscan2
- MUC16 | c.24830C>A p.S8277* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV67462666, COSV67501243; called by muse, mutect2, varscan2
- NEURL2 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51941929; called by muse, varscan2
- OR4K5 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60005456; called by muse, mutect2, varscan2
- PRR23B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.211); catalogued as rs754211034, COSV61493204; called by muse, mutect2, varscan2
- RAX | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV56874439; called by muse, mutect2, varscan2
- REV3L | c.7019C>T p.T2340I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV62618456; called by muse, mutect2, varscan2
- SMC1A | c.3556G>C p.V1186L | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59129052, COSV59131706; called by muse, mutect2, varscan2
- TPBG | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV63882567; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1265758768, COSV54436789; called by muse, mutect2, varscan2
- ZDHHC24 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60080425; called by muse, mutect2, varscan2
- ZFAND1 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1347054485, COSV55107520; called by muse, mutect2, varscan2
- FN3KRP | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FN3KRP | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- LRRTM4 | c.336dup p.E113Rfs*15 | Frame Shift Ins (INS) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- CHRNB4 | c.393C>G p.T131= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV55715892; called by muse, mutect2, varscan2
- OR4K5 | c.876G>A p.R292= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs758059312, COSV60005286; called by muse, mutect2, varscan2
- PLA2G4D | c.1257C>T p.G419= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV51820487; called by muse, mutect2, varscan2
- PPFIBP1 | c.21C>T p.D7= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV57290816; called by muse, mutect2, varscan2
- TMEM26 | c.459G>C p.L153= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV53262058; called by muse, mutect2, varscan2
